Gene-level copy-number profile of tumor specimen TCGA-21-5787-01A from TCGA case TCGA-21-5787, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 65.9 years (24,071 days).
Specimen TCGA-21-5787-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.c2d5ffd7-82a1-47df-8e59-cf7c16530c7d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-5787-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b20ced88-6717-49f8-baa0-fdfbf9c3c7cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 4,365; copy number 2: 25,501; copy number 3: 19,220; copy number 4: 6,779; copy number 5: 2,609; copy number 6: 1,172; copy number 7: 108; copy number 12: 17; copy number 25: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-21-5787-01A-01D-1631-01): tumor purity 0.5, ploidy 2.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:67,001,383–67,003,953, 1 gene: MAST4-AS1.
- chr6:77,460,924–77,463,491, 1 gene: HTR1B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,944 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:74,198,235–86,156,943, 165 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:143,343,180–155,689,000, 567 genes, copy number 5 (broad region; genes not listed).
- chr2:95,789,654–103,529,261, 166 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).
- chr6:167,607–20,500,276, 352 genes, copy number 5–6 (broad region; genes not listed).
- chr6:21,233,168–65,707,226, 1,208 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:78,148,101–81,924,348, 82 genes, copy number 5 (broad region; genes not listed).
- chr8:82,098,451–82,160,577, 1 gene, copy number 5: LINC02839.
- chr8:86,180,418–111,757,710, 403 genes, copy number 5–12 (within-gene range 3–12) (broad region; genes not listed).
- chr8:125,859,721–126,292,788, 1 gene, copy number 25 (within-gene range 3–25): LINC00861.
- chr8:126,174,186–128,564,679, 37 genes, copy number 25: RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr11:9,839,143–9,929,263, 1 gene, copy number 5 (within-gene range 4–5): AC011092.2.
- chr11:9,958,744–10,000,290, 2 genes, copy number 5: AC011092.1, AC011092.3.
- chr11:30,584,130–41,459,773, 133 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:28,133,249–28,581,511, 8 genes, copy number 5: CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1.
- chr12:32,985,838–34,249,958, 20 genes, copy number 6: ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr16:67,518,418–69,085,182, 88 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,967. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
